Somatic mutation profile of tumor specimen TCGA-VQ-A8PZ-01A (aliquot TCGA-VQ-A8PZ-01A-11D-A410-08) from TCGA case TCGA-VQ-A8PZ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 56.8 years (20,735 days).
Specimen TCGA-VQ-A8PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5756b289-e99c-4d52-8ba0-f573addbc07e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PZ-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PZ-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0256956b-a32e-47a1-a754-c9c206a9906d

The open-access MAF lists 82 somatic variants for this specimen: 57 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 22, Intron 3, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRL2 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); catalogued as COSV99590980; called by muse, mutect2, varscan2
- AKNAD1 | c.1449C>A p.S483R | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV100645799; called by muse, mutect2, varscan2
- ALS2CL | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100015270; called by muse, mutect2
- ANK3 | c.7855A>G p.K2619E | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.084); catalogued as COSV99781794; called by muse, mutect2, varscan2
- ARHGAP27 | c.1988A>G p.D663G (on ENST00000428638 / NM_001282290.1; = p.D322G on NM_199282.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV100976595; called by muse, mutect2
- ATP1B4 | c.969A>C p.Q323H (on ENST00000218008 / NM_001142447.3; = p.Q319H on NM_012069.5) | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.91); catalogued as COSV54315475; called by muse, mutect2, varscan2
- CACNA1D | c.3028G>A p.V1010M (on ENST00000350061 / NM_001128840.3; = p.V1030M on NM_000720.4) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs780809499, COSV55442325; called by muse, varscan2
- CD53 | c.192G>A p.M64I | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99602355; called by muse, mutect2, varscan2
- CHRNA3 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs781008848, COSV100468559; called by muse, mutect2, varscan2
- CHRNB4 | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99929544; called by muse, mutect2, varscan2
- DPYSL5 | c.857A>G p.Q286R | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as COSV99982706; called by muse, mutect2
- ETV6 | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56766214; called by muse, mutect2
- FBXO21 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100401840; called by muse, mutect2, varscan2
- FLNA | c.6031T>C p.F2011L (on ENST00000369850 / NM_001110556.2; = p.F2003L on NM_001456.3) | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100775063; called by muse, mutect2, varscan2
- FN3KRP | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV99485086; called by muse, mutect2, varscan2
- GABBR2 | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs267602049, COSV99411025, COSV99411161; called by muse, mutect2, varscan2
- GRIK2 | c.2047G>A p.G683R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100028611; called by muse, mutect2, varscan2
- GRM5 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.306); catalogued as COSV59588537; called by muse, mutect2, varscan2
- HAPLN4 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1024845763, COSV99363987; called by muse, mutect2, varscan2
- HIVEP2 | c.689G>A p.S230N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99175078; called by muse, mutect2
- HOXB13 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749518336, COSV51704962; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLK15 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV56826190, COSV56827776; called by muse, mutect2, varscan2
- LIMS2 | c.190T>G p.C64G (on ENST00000355119 / NM_001161403.3; = p.C88G on NM_017980.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV99760730; called by muse, mutect2, varscan2
- MROH5 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs766229751, COSV71302869; called by muse, mutect2, varscan2
- NEK8 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1163187689, COSV99262191; called by muse, mutect2, varscan2
- NPFFR2 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV58148486; called by muse, mutect2, varscan2
- NXF1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as rs1256598140, COSV53677580; called by muse, mutect2, varscan2
- OR10AG1 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs771819008, COSV56633545; called by muse, mutect2, varscan2
- OR5V1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs761762515, COSV65830108; called by muse, mutect2, varscan2
- OR6N1 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV58650286; called by muse, mutect2, varscan2
- OR8K3 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.244); catalogued as rs767724820; called by muse, mutect2
- PACRG | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100433501; called by muse, mutect2
- PCDHA12 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV56479342; called by muse, mutect2, varscan2
- PCDHB15 | c.1912C>A p.H638N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); catalogued as COSV99179141; called by muse, mutect2, varscan2
- PGBD1 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.258); catalogued as rs200203742, COSV52552833; called by muse, mutect2, varscan2
- PHF14 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1331607804, COSV68855683; called by muse, mutect2
- PLCG1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs774118487, COSV99719210; called by muse, mutect2, varscan2
- RARA | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV54191803, COSV54193672, COSV99565431; called by muse, mutect2, varscan2
- RGS12 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.849); catalogued as rs759834164, COSV60674307; called by muse, mutect2, varscan2
- RHNO1 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs367602600; called by mutect2, varscan2
- RHOA | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV69042372, COSV69043849; called by muse, mutect2, varscan2
- RIMS3 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs751077840, COSV65505042; called by muse, mutect2, varscan2
- SIPA1 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs142497064; called by mutect2, varscan2
- SIX6 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100576427, COSV100576538; called by muse, mutect2, varscan2
- SNAPC2 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as COSV99564319; called by muse, mutect2
- TMC8 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs147103093; called by muse, mutect2, varscan2
- TTN | c.18525A>C p.K6175N (on ENST00000591111; = p.K5248N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | PolyPhen benign (0.167); catalogued as COSV100625965; called by muse, mutect2, varscan2
- UGGT2 | c.491G>T p.R164I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV100942635; called by muse, mutect2, varscan2
- UNC5C | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.824); catalogued as rs371874775; called by muse, mutect2, varscan2
- VIPR1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs201431086, COSV57298962; called by muse, varscan2
- WDR33 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100460555; called by muse, mutect2
- ZFP42 | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs576365857, COSV58817581; called by muse, mutect2, varscan2
- ZNF609 | c.1742G>A p.S581N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100441652; called by muse, mutect2, varscan2
- ZP4 | c.686C>G p.T229R | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100850754; called by muse, mutect2, varscan2
- EXOSC10 | c.2040del p.A681Pfs*93 (on ENST00000376936 / NM_001001998.3; = p.A681Pfs*14 on NM_002685.4) | Frame Shift Del (DEL) | VAF 32/189 reads (17%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by mutect2, varscan2
- ASXL1 | c.621C>T p.S207= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs1228680740, COSV100038579; called by muse, mutect2, varscan2
- ATP6V1H | c.861A>G p.A287= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100778782; called by muse, mutect2, varscan2
- CADM1 | c.873C>T p.A291= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as rs528617309, COSV100523243; called by muse, mutect2, varscan2
- CEP68 | c.2022T>C p.D674= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99561179; called by muse, mutect2, varscan2
- DCAF12L2 | c.321C>T p.N107= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV63581208; called by muse, mutect2, varscan2
- FASTKD2 | c.75C>T p.F25= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99379197; called by muse, mutect2, varscan2
- FOXD4 | c.1200G>A p.A400= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs763686353, COSV58702044; called by muse, mutect2, varscan2
- GRIA3 | c.669C>T p.V223= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs751784028, COSV52079963; called by muse, mutect2, varscan2
- KCNA1 | c.1047G>A p.A349= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs748570236, COSV66836519; called by muse, mutect2, varscan2
- KRT28 | c.582C>T p.N194= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as rs772215881, COSV100137681; called by muse, mutect2, varscan2
- LRFN1 | c.462G>T p.S154= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs757353043, COSV99953260; called by muse, varscan2
- MYO18B | c.1749C>T p.N583= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs544050546, COSV100124824; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1029C>T p.T343= (on ENST00000421990 / NM_001136042.2; = p.T325= on NM_025267.3) | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100799406; called by muse, mutect2
- RAD54L2 | c.3006C>T p.P1002= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs145871194, COSV99621080, COSV99621712; called by mutect2, varscan2
- SFRP2 | c.396C>T p.F132= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV56836953; called by muse, mutect2
- SOST | c.351C>T p.N117= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100059761; called by muse, mutect2, varscan2
- TNS1 | c.708C>T p.I236= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs1364036682, COSV50705200; called by muse, mutect2, varscan2
- TRPC3 | c.519G>A p.A173= (on ENST00000379645 / NM_001366479.2; = p.A100= on NM_003305.2) | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs201407818, COSV53372527; called by muse, mutect2, varscan2
- TSHZ3 | c.2169C>T p.S723= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs527386010, COSV53677774; called by mutect2, varscan2
- WASHC4 | c.3255A>G p.R1085= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1238324386, COSV100162693; called by muse, mutect2, varscan2
- ZNF331 | c.831G>A p.G277= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99467807; called by muse, mutect2, varscan2
- ZNF765 | c.1347C>T p.F449= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV101125546; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-148G>A | Intron (SNP) | VAF 12/92 reads (13%) | catalogued as COSV68923847; called by muse, mutect2, varscan2
- OBSCN | c.18662-2365C>T | Intron (SNP) | VAF 10/44 reads (23%) | catalogued as rs376946873; called by muse, mutect2, varscan2
- TTN | c.10360+4108G>A | Intron (SNP) | VAF 5/53 reads (9%) | catalogued as rs1405565042, COSV59902595; called by muse, mutect2, varscan2
